TCGA case TCGA-EE-A29Q — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6a1818f9-9303-41b0-b3b7-07faf5055c86

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 70 years; Vital status: Dead; Days to death: 2,030 days (5.6 years).

Diagnoses (10)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C49.1; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Classification of tumor: Progression; Age at diagnosis: 73.2 years (26,737 days); Days to diagnosis: 890 days (2.4 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.8 years (25,847 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,351 days (3.7 years); Days to treatment end: 1,397 days (3.8 years); Treatment dose: 54 Gy; Number of fractions: 27; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dacarbazine; Days to treatment start: 1,837 days (5.0 years); Days to treatment end: 1,858 days (5.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,962 days (5.4 years); Days to treatment end: 1,968 days (5.4 years); Treatment dose: 20 Gy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,976 days (5.4 years); Days to treatment end: 1,982 days (5.4 years); Treatment dose: 20 Gy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 74.2 years (27,103 days); Days to diagnosis: 1,256 days (3.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,298 days (3.6 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 75.1 years (27,421 days); Days to diagnosis: 1,574 days (4.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 75.7 years (27,643 days); Days to diagnosis: 1,796 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Adrenal gland, NOS. Age at diagnosis: 75.7 years (27,643 days); Days to diagnosis: 1,796 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
8. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Bone, NOS. Age at diagnosis: 75.7 years (27,643 days); Days to diagnosis: 1,796 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
9. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 75.7 years (27,643 days); Days to diagnosis: 1,796 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
10. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 75.7 years (27,647 days); Days to diagnosis: 1,800 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,800 days (4.9 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (9 entries)
- Days to follow up: 1,136 days (3.1 years); Disease response: Tumor Free.
- Day 1,256 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 1,256 days (3.4 years).
- Day 1,574 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 1,574 days (4.3 years).
- Day 1,796 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 1,796 days (4.9 years).
- Day 1,796 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,796 days (4.9 years).
- Day 1,796 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 1,796 days (4.9 years).
- Day 1,796 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,796 days (4.9 years).
- Day 1,800 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,800 days (4.9 years).
- Days to follow up: 2,030 days (5.6 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A29Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A29Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-EE-A29Q-06A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A29Q-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 2.3; Primary melanoma mitotic rate: 8; Radiation therapy to primary: No; Primary location: Regional Cutaneous or Subcutaneous Tissue (includes satellite and in-transit metastasis); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,030 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,030 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,256 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A29Q-06A-11D-A191-01): tumor purity 0.86, ploidy 1.77, whole-genome doublings 0.
